Gene-level copy-number profile of tumor specimen AP-HFEA-AE from APOLLO case AP-HFEA, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3.
Specimen AP-HFEA-AE: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 970dffa6-1907-40ae-8e23-fc890d17c675.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-HFEA-T7 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/bb6b697f-c72b-4730-b6dc-4d893384ef75

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 6,787; copy number 2: 50,880; copy number 3: 701.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–3): AL589739.1.
- chr1:246,682,108–246,691,821, 2 genes: AL591848.2, AL591848.1.
- chr2:197,569–209,892, 1 gene: AC079779.1.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr5:79,170,234–79,230,588, 4 genes (within-gene range 0–2): RNY3P1, AC016559.2, AC016559.1, AC016559.3.
- chr5:174,724,582–174,730,896, 1 gene: MSX2.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr7:62,275,361–63,011,569, 2 genes: AC128676.1, RNU6-417P.
- chr9:40,767,870–40,883,763, 2 genes (within-gene range 0–1): AL353626.1, AL353626.2.
- chr10:42,149,310–42,149,549, 1 gene: KSR1P1.
- chr13:100,027,769–100,088,950, 3 genes: NDUFA12P1, PCCA-DT, ASNSP3.
- chr20:62,302,093–62,308,862, 2 genes (within-gene range 0–2): ADRM1, AL354836.1.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–2): MIR4758.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.
- chr21:44,350,163–44,443,081, 4 genes (within-gene range 0–2): TRPM2, TRPM2-AS, AP001065.2, AP001065.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
